Somatic mutation profile of tumor specimen TCGA-55-8092-01A (aliquot TCGA-55-8092-01A-11D-2238-08) from TCGA case TCGA-55-8092, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.6 years (27,597 days).
Specimen TCGA-55-8092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 514d32f1-f689-47bc-b748-2a831cc21d37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8092-10A (Blood Derived Normal), aliquot TCGA-55-8092-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/035231ec-5900-4d97-a10f-e39bd2c932fc

The open-access MAF lists 617 somatic variants for this specimen: 449 protein-altering or splice-affecting, 157 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 396, Silent 157, Nonsense Mutation 27, Frame Shift Del 12, Splice Site 8, Intron 5, RNA 3, Splice Region 3, 3'UTR 2, Frame Shift Ins 2, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/214 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 46/124 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3194C>T p.T1065M | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776877163, COSV55946264; called by muse, mutect2, varscan2
- ABCC6 | c.2749G>T p.G917* | Nonsense Mutation (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99228284; called by muse, mutect2
- ABHD1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs370322556; called by muse, mutect2, varscan2
- ABL2 | c.941T>G p.V314G (on ENST00000502732 / NM_007314.4; = p.V299G on NM_005158.5) | Missense Mutation (SNP) | VAF 164/285 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100772557; called by muse, mutect2, varscan2
- ACAN | c.4931C>T p.S1644F | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100717350; called by muse, mutect2, varscan2
- ACTL8 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV100958532; called by muse, mutect2, varscan2
- ADAMTS5 | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs532699369, COSV99537196; called by muse, mutect2, varscan2
- ADAMTS5 | c.1258C>A p.H420N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99537198; called by muse, mutect2, varscan2
- ADAMTS7 | c.4170G>C p.E1390D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as COSV101183038; called by muse, mutect2
- ADGRE1 | c.1752G>T p.M584I | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV99165092; called by muse, mutect2, varscan2
- ADGRE1 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.108); catalogued as COSV99165093; called by muse, mutect2, varscan2
- ADGRV1 | c.6782A>G p.N2261S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV101315602; called by muse, mutect2
- ADNP2 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100080610, COSV51542100; called by muse, mutect2, varscan2
- AHCYL2 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as rs745705126, COSV100273077; called by muse, mutect2, varscan2
- AKAP6 | c.4446G>A p.M1482I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV55214471; called by muse, mutect2, varscan2
- ALDH16A1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs1045288160, COSV99512672; called by muse, mutect2, varscan2
- ALG10B | c.1329C>G p.C443W | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100439830; called by muse, mutect2, varscan2
- AMOT | c.2302C>T p.R768C (on ENST00000371959 / NM_001113490.1; = p.R359C on NM_133265.3) | Missense Mutation (SNP) | VAF 97/347 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59060024; called by muse, mutect2, varscan2
- ANTXR1 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100362063; called by muse, mutect2, varscan2
- APAF1 | c.3619G>T p.G1207W (on ENST00000551964 / NM_181861.2; = p.G1153W on NM_001160.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243606; called by muse, mutect2, varscan2
- APOB | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99264262; called by muse, mutect2, varscan2
- ARAP2 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100394266; called by muse, mutect2, varscan2
- ARHGAP21 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100255900; called by muse, mutect2, varscan2
- ARHGAP29 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV99557783; called by muse, mutect2, varscan2
- ARHGEF37 | c.511A>T p.R171W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381976; called by muse, mutect2, varscan2
- ARMCX2 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV100168072; called by muse, mutect2, varscan2
- ASTN1 | c.3105C>A p.S1035R | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1394091210, COSV100705707, COSV62504075; called by muse, mutect2, varscan2
- ASXL1 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.106); catalogued as COSV60106341, COSV60111078, COSV60113023; called by muse, mutect2, varscan2
- ATP6V1E2 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as COSV60575874; called by muse, mutect2, varscan2
- BAAT | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.142); catalogued as COSV104387741, COSV99408403; called by muse, mutect2, varscan2
- BAZ1B | c.2108A>T p.E703V | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV100289632; called by muse, mutect2
- BCKDHB | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs747674891, COSV100243329; called by muse, mutect2
- BMT2 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99774482; called by muse, mutect2, varscan2
- BPIFC | c.1397T>C p.L466P | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.671); catalogued as COSV99321984; called by muse, mutect2, varscan2
- BPNT2 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99388890; called by muse, mutect2
- BRINP3 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100818459, COSV66524105; called by muse, mutect2, varscan2
- BTNL8 | c.1261T>A p.F421I | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99180431; called by muse, mutect2, varscan2
- C11orf68 | c.745G>T p.E249* (on ENST00000530188; = p.E290* on NM_031450.4) | Nonsense Mutation (SNP) | VAF 42/204 reads (21%) | catalogued as COSV100437057; called by muse, mutect2, varscan2
- C16orf46 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100215159; called by muse, mutect2, varscan2
- C3orf14 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV51707702, COSV99223699; called by muse, mutect2, varscan2
- CA1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV56278217; called by muse, mutect2
- CA9 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 62/631 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253072; called by muse, mutect2
- CADM2 | c.679C>A p.P227T (on ENST00000407528 / NM_001167674.2; = p.P229T on NM_153184.4) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053361, COSV67407947; called by muse, mutect2, varscan2
- CCDC170 | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV99498230; called by muse, mutect2, varscan2
- CCDC180 | c.3560T>A p.L1187Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100826610; called by muse, mutect2, varscan2
- CCDC39 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99867714, COSV99870239; called by muse, mutect2, varscan2
- CCDC74B | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV100134243; called by muse, mutect2, varscan2
- CD180 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99842134; called by muse, mutect2, varscan2
- CD244 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as rs144670683; called by muse, mutect2, varscan2
- CD300LD | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV100032329; called by muse, mutect2, varscan2
- CD82 | c.261G>T p.L87= | Splice Region (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99907430; called by muse, mutect2
- CDH8 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100180067; called by muse, mutect2, varscan2
- CDX4 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100999113, COSV100999124; called by muse, mutect2, varscan2
- CEACAM20 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100386817, COSV57600990; called by muse, mutect2
- CEBPZ | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV99305086; called by muse, mutect2, varscan2
- CFAP58 | c.987C>G p.I329M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100458795; called by muse, mutect2, varscan2
- CHD3 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100390873; called by muse, mutect2, varscan2
- CHRM3 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV99697741; called by muse, mutect2
- CLEC16A | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1366471211, COSV101277819; called by muse, mutect2, varscan2
- CLEC1A | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100191222, COSV100191244; called by muse, mutect2, varscan2
- CLEC3A | c.492C>A p.D164E (on ENST00000651443; = p.D155E on NM_005752.6) | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as rs746748496, COSV100222101; called by muse, mutect2, varscan2
- CLEC3A | c.493C>G p.R165G (on ENST00000651443; = p.R156G on NM_005752.6) | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs770103147, COSV100222103, COSV55221365; called by muse, mutect2, varscan2
- CLRN1 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769266039, COSV99045529; called by muse, mutect2, varscan2
- CNGB3 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as rs1563747899, COSV100181479, COSV60684550; called by muse, mutect2
- CNKSR2 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV54264675; called by muse, varscan2
- CNTN5 | c.2590C>A p.Q864K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99674128; called by muse, mutect2, varscan2
- COCH | c.328A>G p.K110E (on ENST00000216361 / NM_001347720.1; = p.K45E on NM_004086.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99363450; called by muse, mutect2, varscan2
- COL11A1 | c.3979G>T p.G1327C | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615476, COSV100617332; called by muse, mutect2, varscan2
- COL21A1 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99777782; called by muse, varscan2
- COL22A1 | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100276901; called by muse, mutect2, varscan2
- COL4A1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.582); catalogued as COSV101011005; called by muse, mutect2, varscan2
- CPED1 | c.2801C>A p.T934K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60007522; called by muse, mutect2, varscan2
- CR1 | c.5366C>A p.P1789H | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100887431, COSV100887707; called by muse, mutect2, varscan2
- CRACD | c.2365T>A p.C789S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99948804; called by muse, mutect2, varscan2
- CRB1 | c.2038C>A p.P680T | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043057714, COSV66332901; called by muse, mutect2
- CRMP1 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV100271505; called by muse, mutect2, varscan2
- CRTC1 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 205/582 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1219528313, COSV58724551; called by muse, mutect2, varscan2
- CSMD3 | c.9895C>A p.Q3299K (on ENST00000297405 / NM_001363185.1; = p.Q3130K on NM_052900.3) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV52213913; called by muse, mutect2, varscan2
- CTNNA2 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV63570435; called by muse, mutect2, varscan2
- CTNNA2 | c.2368A>C p.N790H | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559631; called by muse, mutect2, varscan2
- CUBN | c.9794A>G p.E3265G | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as COSV100912216; called by muse, mutect2, varscan2
- CYP1A2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100673865; called by muse, varscan2
- CYP2C19 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 68/381 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV100990237, COSV100990280; called by muse, mutect2, varscan2
- CYP51A1 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV50154506, COSV99133668; called by muse, mutect2, varscan2
- DCC | c.1996A>C p.T666P | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV100498696; called by muse, mutect2, varscan2
- DCDC1 | c.2849G>C p.R950T (on ENST00000597505 / NM_001367979.1; = p.R57T on NM_020869.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100337953, COSV60312898; called by muse, mutect2, varscan2
- DCDC1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100662904; called by muse, mutect2, varscan2
- DDX59 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100494444, COSV58753871; called by muse, mutect2, varscan2
- DEGS2 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs200113406, COSV99979071; called by muse, mutect2
- DGKB | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99337240; called by muse, mutect2
- DGKB | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV99337244; called by muse, mutect2
- DHFR | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101459023; called by muse, mutect2, varscan2
- DIDO1 | c.5840G>T p.G1947V | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99825108; called by muse, mutect2, varscan2
- DIDO1 | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56634291, COSV99825111; called by muse, mutect2, varscan2
- DLG5 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100967320; called by muse, mutect2, varscan2
- DLGAP4 | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV100210934; called by muse, mutect2, varscan2
- DMBX1 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs539861883, COSV100760692; called by muse, mutect2, varscan2
- DNAH7 | c.8752C>A p.L2918I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100414276, COSV100416127; called by muse, mutect2, varscan2
- DNAH8 | c.6184G>A p.E2062K | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100543803; called by muse, mutect2, varscan2
- DOCK7 | c.1742G>A p.R581K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51996742, COSV99223418; called by muse, mutect2, varscan2
- DPM1 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs772672531, COSV99724192; called by muse, mutect2, varscan2
- DPRX | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV99060230; called by muse, mutect2, varscan2
- DSC1 | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV57150429, COSV99937351; called by muse, mutect2, varscan2
- DSG4 | c.2995C>T p.P999S | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.974); catalogued as COSV100355529; called by muse, mutect2, varscan2
- DUSP29 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs747727628, COSV100633248; called by muse, mutect2, varscan2
- EIF3G | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1238973948, COSV99460981; called by muse, mutect2, varscan2
- EMX2 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV101463583; called by muse, mutect2, varscan2
- EPHB2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs139122679; called by mutect2, varscan2
- EPHB4 | c.2788G>T p.A930S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.294); catalogued as COSV100639432; called by muse, mutect2, varscan2
- ERAP2 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV101163537; called by muse, mutect2, varscan2
- ERICH3 | c.3590C>T p.S1197F | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58599622, COSV58610615; called by muse, mutect2, varscan2
- ETFB | c.76A>T p.R26W | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV100495551; called by muse, mutect2, varscan2
- ETV2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1334526935, COSV99876813; called by muse, mutect2, varscan2
- EXOC4 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs924973063, COSV54109967, COSV99552796; called by muse, mutect2, varscan2
- F7 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121964930, CM960534, COSV100660964; called by muse, varscan2
- FAM124A | c.1545C>A p.C515* (on ENST00000322475 / NM_001242312.2; = p.C551* on NM_145019.4) | Nonsense Mutation (SNP) | VAF 25/180 reads (14%) | catalogued as rs189898463, COSV99696209; called by muse, mutect2, varscan2
- FAM153CP | n.365-1G>A | Splice Site (SNP) | VAF 34/585 reads (6%) | catalogued as COSV101228637; called by muse, mutect2
- FAM24A | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 92/664 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1235954887, COSV100925072; called by muse, mutect2, varscan2
- FAM83C | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV100981531; called by muse, mutect2, varscan2
- FAR1 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100701517; called by muse, mutect2
- FARP2 | c.2371G>A p.G791R | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV99884161; called by muse, mutect2, varscan2
- FASTKD5 | c.1366A>T p.S456C | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV99417544; called by muse, mutect2, varscan2
- FBN1 | c.937T>A p.C313S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as CD063527, COSV100354184; called by muse, mutect2, varscan2
- FCHO2 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99821534; called by muse, mutect2, varscan2
- FCHSD1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781226; called by muse, mutect2, varscan2
- FMN2 | c.2737C>A p.P913T | Missense Mutation (SNP) | VAF 57/468 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.767); catalogued as COSV100143684; called by muse, mutect2, varscan2
- FMN2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs370099468; called by muse, varscan2
- FPGT-TNNI3K | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs761751877, COSV100435957; called by muse, mutect2, varscan2
- FRG2C | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1457071002; called by muse, mutect2, varscan2
- FRYL | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99976214; called by muse, mutect2, varscan2
- FTO | c.752-2A>G p.X251_splice | Splice Site (SNP) | VAF 21/109 reads (19%) | catalogued as COSV101149772; called by muse, mutect2, varscan2
- FZD10 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472720, COSV99969297; called by muse, mutect2, varscan2
- FZD6 | c.1487G>C p.S496T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100708328; called by muse, mutect2, varscan2
- G6PC2 | c.258A>C p.E86D | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV99960680; called by muse, mutect2, varscan2
- GABRB1 | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV99780587; called by muse, mutect2
- GABRG1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54954723, COSV99777566; called by muse, mutect2, varscan2
- GAS2 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1348892455, COSV99534817; called by muse, mutect2, varscan2
- GAS2L2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1330021941; called by muse, mutect2, varscan2
- GDPD2 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100978567; called by muse, mutect2, varscan2
- GET3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628144, COSV62002359; called by muse, mutect2, varscan2
- GFRA1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as COSV100815559; called by muse, mutect2, varscan2
- GJA10 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101005296; called by muse, mutect2, varscan2
- GPAT3 | c.996+1G>T p.X332_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100022825; called by muse, mutect2, varscan2
- GPATCH4 | c.1109G>C p.R370T | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100576891; called by muse, mutect2, varscan2
- GPR119 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV99358558; called by muse, mutect2, varscan2
- GPR142 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV100170712, COSV59518631; called by muse, mutect2, varscan2
- GPR156 | c.2067A>T p.R689S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100251201; called by muse, mutect2, varscan2
- GPR37 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100390631; called by muse, mutect2, varscan2
- GRAMD1B | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100454401; called by muse, mutect2, varscan2
- GUCA1B | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as COSV100027671, COSV57834867; called by muse, mutect2, varscan2
- H2AC6 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100019793; called by muse, mutect2, varscan2
- H3-4 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100797365; called by muse, mutect2, varscan2
- HELB | c.787A>T p.R263* | Nonsense Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as COSV99921668; called by muse, mutect2, varscan2
- HEPH | c.108G>T p.Q36H (on ENST00000343002; = p.Q90H on NM_138737.5) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100294317; called by muse, mutect2, varscan2
- HEPH | c.2830G>T p.G944W (on ENST00000343002; = p.G677W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV100294321; called by muse, mutect2, varscan2
- HIPK1 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100478603; called by muse, mutect2, varscan2
- HIPK3 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV100305513; called by muse, mutect2, varscan2
- HMCN1 | c.6029-2A>T p.X2010_splice | Splice Site (SNP) | VAF 46/217 reads (21%) | catalogued as COSV99625587; called by muse, mutect2, varscan2
- HMGB4 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99587165; called by muse, mutect2, varscan2
- HMGCS2 | c.737T>A p.L246* | Nonsense Mutation (SNP) | VAF 14/110 reads (13%) | catalogued as COSV101024703; called by muse, mutect2, varscan2
- HP1BP3 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100391609; called by muse, mutect2, varscan2
- HSPA6 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100553979; called by muse, mutect2
- HTN3 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV101126161; called by muse, mutect2, varscan2
- HTR1E | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100540995; called by muse, mutect2, varscan2
- HTT | c.8095G>A p.E2699K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100750543; called by muse, mutect2, varscan2
- IGSF1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.133); catalogued as COSV100811925, COSV63837095; called by muse, mutect2, varscan2
- IL21R | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs36031126, COSV61968589; called by muse, mutect2, varscan2
- INF2 | c.1910A>G p.K637R | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as COSV99383594; called by muse, mutect2, varscan2
- IQGAP3 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV100752092; called by muse, mutect2, varscan2
- IRAG2 | c.3073G>T p.D1025Y (on ENST00000636465; = p.D70Y on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1408595228, COSV100611713; called by muse, mutect2, varscan2
- IRF8 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs945535357, COSV99236176; called by muse, mutect2
- ITGA8 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100958992; called by muse, mutect2, varscan2
- ITIH2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623202; called by muse, mutect2
- JAG1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV99652570; called by muse, mutect2, varscan2
- JHY | c.539A>C p.Q180P | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99912856; called by muse, mutect2, varscan2
- KCNB2 | c.2295C>A p.D765E | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV101578693; called by muse, mutect2
- KCNG1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs919816936, COSV65367937; called by muse, varscan2
- KCNJ1 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131201; called by muse, mutect2, varscan2
- KCNQ3 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV101195757; called by muse, mutect2, varscan2
- KDM4B | c.2588C>T p.S863L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV50211269; called by muse, mutect2, varscan2
- KDSR | c.880-2A>T p.X294_splice | Splice Site (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100430180; called by muse, mutect2, varscan2
- KIAA0895L | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99220433; called by muse, mutect2, varscan2
- KIF19 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100738986; called by muse, mutect2, varscan2
- KIF1A | c.2407G>C p.E803Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as COSV100240104; called by muse, mutect2, varscan2
- KIF21B | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs543715577, COSV100143980; called by muse, mutect2, varscan2
- KLHL34 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs931517917, COSV65279249; called by muse, mutect2, varscan2
- KMT2E | c.2096C>A p.T699K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs776425763, COSV99995959; called by muse, mutect2, varscan2
- KRT3 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100526935; called by muse, mutect2, varscan2
- KRT83 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as COSV99531416; called by muse, mutect2, varscan2
- LAMA2 | c.7808C>A p.A2603E | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV70356039; called by muse, mutect2, varscan2
- LAMB3 | c.3303G>T p.Q1101H | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as COSV99151649; called by muse, mutect2, varscan2
- LAMB3 | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100620165; called by muse, mutect2, varscan2
- LCE2D | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs113433987; called by muse, mutect2, varscan2
- LGR6 | c.1879G>A p.G627S (on ENST00000367278 / NM_001017403.1; = p.G575S on NM_021636.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99706311; called by muse, mutect2, varscan2
- LPIN2 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99858089; called by muse, mutect2, varscan2
- LRIG2 | c.839A>G p.K280R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV100743055; called by muse, mutect2, varscan2
- LRP2 | c.5576C>T p.T1859I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.929); catalogued as rs1426246885, COSV99787006; called by muse, mutect2, varscan2
- LRRN3 | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100068685; called by muse, mutect2, varscan2
- LTBP1 | c.3967A>T p.M1323L (on ENST00000404816 / NM_206943.4; = p.M997L on NM_000627.4) | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV99697943; called by muse, mutect2, varscan2
- LTBP1 | c.4066G>T p.A1356S (on ENST00000404816 / NM_206943.4; = p.A1030S on NM_000627.4) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.632); catalogued as rs569029644, COSV55383165; called by muse, mutect2, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MAP1B | c.2911C>A p.P971T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99701960; called by muse, mutect2, varscan2
- MAP1B | c.6628C>A p.P2210T | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99701963; called by muse, mutect2, varscan2
- MAS1L | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as rs1343892548, COSV101009652; called by muse, mutect2, varscan2
- MASP2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV101280089; called by muse, mutect2, varscan2
- MCMBP | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1483980605, COSV63509820, COSV63510920; called by muse, mutect2, varscan2
- MDFIC | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as COSV99994952; called by muse, mutect2
- MED7 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99644209; called by muse, mutect2, varscan2
- MERTK | c.1920C>A p.C640* | Nonsense Mutation (SNP) | VAF 31/143 reads (22%) | catalogued as COSV99774236; called by muse, mutect2, varscan2
- MFAP3 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100491524; called by muse, mutect2, varscan2
- MICAL3 | c.3233C>T p.S1078L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as rs1327166044, COSV101490818; called by muse, mutect2, varscan2
- MOV10 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99588120; called by muse, mutect2, varscan2
- MROH5 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as rs780202794, COSV71302417; called by muse, mutect2, varscan2
- MSH3 | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | catalogued as rs748016039, COSV99432656, COSV99433283; called by muse, mutect2, varscan2
- MTCL1 | c.2410C>A p.L804I (on ENST00000306329 / NM_001378206.1; = p.L444I on NM_015210.4) | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100093783; called by muse, mutect2, varscan2
- MTG1 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 67/487 reads (14%) | catalogued as COSV53371581, COSV99529715; called by muse, mutect2, varscan2
- MUC17 | c.2470A>G p.S824G | Missense Mutation (SNP) | VAF 86/805 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs1327822904, COSV100072146; called by muse, varscan2
- MUC17 | c.6575T>G p.V2192G | Missense Mutation (SNP) | VAF 350/1086 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100072147; called by muse, varscan2
- MXRA5 | c.4894T>A p.Y1632N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV99476093; called by muse, mutect2, varscan2
- MYH3 | c.2467A>T p.M823L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56867595, COSV99877880; called by muse, mutect2, varscan2
- MYH7 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs372731424, CM973125, COSV100805812; called by muse, mutect2, varscan2
- MYH8 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV101238300; called by muse, mutect2, varscan2
- MYO1F | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.47); catalogued as COSV100596446; called by muse, mutect2, varscan2
- MYOF | c.2869-1G>C p.X957_splice | Splice Site (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100825387; called by muse, mutect2, varscan2
- MYT1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1389044573, COSV100114214; called by muse, mutect2, varscan2
- NCF4 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs572795915, COSV99957180; called by muse, mutect2, varscan2
- NCKAP1L | c.2754G>T p.R918S | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99514663; called by muse, mutect2, varscan2
- NCR1 | c.342T>A p.D114E | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV99400811; called by muse, mutect2, varscan2
- NECTIN1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.326); catalogued as COSV99871879; called by muse, mutect2, varscan2
- NELL1 | c.506+1G>T p.X169_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100119612; called by muse, mutect2
- NES | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100957790; called by muse, mutect2, varscan2
- NEURL4 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.204); catalogued as COSV100223940; called by muse, mutect2, varscan2
- NFX1 | c.1149G>C p.L383F | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100581889; called by muse, mutect2
- NID2 | c.128G>C p.W43S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV99356104; called by muse, mutect2, varscan2
- NIPSNAP1 | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99331066; called by muse, mutect2, varscan2
- NKX2-2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs761265871, COSV101010520, COSV65819920; called by muse, mutect2, varscan2
- NLGN3 | c.889C>T p.L297F (on ENST00000358741 / NM_181303.2; = p.L277F on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62444736; called by muse, mutect2, varscan2
- NLRP2 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV99671997; called by muse, mutect2, varscan2
- NMUR2 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1561695723, COSV99676699; called by muse, mutect2, varscan2
- NPTX2 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 50/445 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55719883; called by muse, mutect2, varscan2
- NSD1 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.967); catalogued as COSV100728577; called by muse, mutect2, varscan2
- NSD3 | c.3237C>G p.N1079K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1292827625, COSV100395088; called by muse, mutect2, varscan2
- NTHL1 | c.868T>C p.C290R (on ENST00000219066; = p.C282R on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54594618, COSV99526171; called by muse, mutect2, varscan2
- NTRK3 | c.2501A>T p.Y834F (on ENST00000360948 / NM_001012338.2; = p.Y820F on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100712379; called by muse, mutect2, varscan2
- OCA2 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100667071; called by muse, mutect2, varscan2
- OLFM2 | c.1018C>A p.Q340K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV99321588; called by muse, mutect2, varscan2
- OLFM2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV99321590; called by muse, mutect2, varscan2
- OPRPN | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV101271076, COSV68192548; called by muse, mutect2, varscan2
- OR10G4 | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100304735; called by muse, varscan2
- OR10G7 | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389810; called by muse, mutect2
- OR2L2 | c.474C>A p.H158Q | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.838); catalogued as COSV100823279; called by muse, mutect2, varscan2
- OR2M3 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as COSV101513406; called by muse, mutect2, varscan2
- OR2T33 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100531706; called by muse, mutect2, varscan2
- OR5M1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV101591540; called by muse, mutect2, varscan2
- OR6F1 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129018; called by muse, mutect2
- OR8A1 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.213); catalogued as COSV99420392; called by muse, mutect2, varscan2
- OSBPL2 | c.1000G>A p.E334K (on ENST00000313733 / NM_144498.4; = p.E322K on NM_014835.4) | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV100569172; called by muse, mutect2
- OVCH1 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100548308; called by muse, mutect2, varscan2
- P2RX6 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs750786718, COSV100298557; called by muse, mutect2
- PADI3 | c.1537C>A p.L513M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as COSV100968431; called by muse, mutect2, varscan2
- PCDH11X | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 46/164 reads (28%) | catalogued as COSV100009348; called by muse, mutect2, varscan2
- PCDH15 | c.4892T>A p.L1631Q (on ENST00000644397 / NM_001354429.2; = p.L1573Q on NM_001142771.2) | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); catalogued as COSV100903428; called by muse, mutect2, varscan2
- PCDH15 | c.4954C>A p.Q1652K | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as COSV100217206; called by muse, mutect2, varscan2
- PCDH18 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100787107; called by muse, mutect2, varscan2
- PCDHA11 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100248557; called by muse, mutect2, varscan2
- PCDHA3 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100793230; called by muse, mutect2, varscan2
- PCDHA3 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV63543761; called by muse, mutect2, varscan2
- PCDHA9 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs781945515, COSV100969196; called by muse, mutect2, varscan2
- PCDHB7 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.239); catalogued as COSV99176262; called by muse, mutect2, varscan2
- PCDHGA6 | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV53999578, COSV99533252; called by muse, mutect2, varscan2
- PCDHGA8 | c.1430A>T p.H477L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV99533255; called by muse, mutect2, varscan2
- PCDHGB2 | c.926T>A p.F309Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.776); catalogued as COSV99533248; called by muse, mutect2, varscan2
- PCDHGB3 | c.531C>A p.H177Q | Missense Mutation (SNP) | VAF 113/394 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV99533251; called by muse, mutect2, varscan2
- PCOLCE | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV99575075; called by muse, mutect2, varscan2
- PDE4DIP | c.6736G>T p.E2246* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV57686215; called by muse, mutect2, varscan2
- PDGFD | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158235; called by muse, mutect2, varscan2
- PDHA2 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99756613; called by muse, mutect2, varscan2
- PDZK1IP1 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99595560; called by muse, mutect2, varscan2
- PHTF2 | c.1913C>T p.S638F (on ENST00000248550 / NM_001366089.1; = p.S600F on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99301234; called by muse, mutect2, varscan2
- PIRT | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1178354230, COSV101652668; called by muse, mutect2, varscan2
- PLAAT2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV99738081; called by muse, mutect2, varscan2
- PLG | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99804352; called by muse, mutect2, varscan2
- PLPPR4 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64564197, COSV64567996; called by muse, mutect2, varscan2
- PLXNA2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.923); catalogued as COSV100885220; called by muse, mutect2, varscan2
- PNLIP | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769861164, COSV100981647; called by muse, mutect2, varscan2
- POLR1B | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99637321; called by muse, mutect2, varscan2
- PRDM10 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV100456623; called by muse, mutect2, varscan2
- PREX1 | c.1594C>A p.R532S | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100906099, COSV64247589; called by muse, mutect2, varscan2
- PRKAG2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV99834938; called by muse, mutect2, varscan2
- PRKCA | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV52593918, COSV52594468; called by muse, mutect2, varscan2
- PRKCQ | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 200/473 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99576488; called by muse, varscan2
- PRLHR | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99492698; called by muse, mutect2, varscan2
- PROM2 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100468748; called by muse, mutect2, varscan2
- PTPN11 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100692277; called by muse, mutect2
- PTPRZ1 | c.6153G>C p.K2051N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101099740, COSV66436056; called by muse, mutect2, varscan2
- RBBP6 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100154333; called by muse, mutect2
- RBBP6 | c.4070C>T p.S1357L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs950351327, COSV100154335; called by muse, mutect2
- RBMXL1 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as COSV99555725; called by muse, mutect2, varscan2
- RC3H1 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV99281126; called by muse, mutect2, varscan2
- RFLNA | c.328G>A p.E110K (on ENST00000546355 / NM_001365156.1; = p.E29K on NM_181709.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV100133245, COSV100133426; called by muse, mutect2, varscan2
- RHOU | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 26/217 reads (12%) | catalogued as COSV100797141; called by muse, mutect2, varscan2
- RNF20 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.932); catalogued as COSV100874302; called by muse, mutect2, varscan2
- ROBO2 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1304881393, COSV100164915; called by muse, mutect2, varscan2
- ROBO4 | c.2482T>G p.Y828D | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100127361; called by muse, mutect2, varscan2
- RP1L1 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101223032; called by muse, mutect2, varscan2
- RPTOR | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 83/669 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100155455; called by muse, mutect2, varscan2
- RRAGD | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV63269279; called by muse, mutect2, varscan2
- RTN4IP1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs867884074, COSV100945189; called by muse, mutect2, varscan2
- RWDD2B | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99725558; called by muse, mutect2, varscan2
- RYR1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.895); catalogued as COSV100614935; called by muse, mutect2, varscan2
- RYR2 | c.2931G>T p.K977N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100768759; called by muse, mutect2
- RYR2 | c.12920G>T p.R4307L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV63684322, COSV63691311; called by muse, mutect2, varscan2
- RYR3 | c.7498A>C p.K2500Q (on ENST00000389232; = p.K2501Q on NM_001036.6) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101212177; called by muse, mutect2
- SBF2 | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99813533; called by muse, mutect2, varscan2
- SCAF11 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV101014135; called by muse, mutect2, varscan2
- SCEL | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs200625008, COSV62994688; called by muse, mutect2, varscan2
- SCN9A | c.3066G>T p.R1022S (on ENST00000303354; = p.R1011S on NM_002977.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV100311841; called by muse, mutect2, varscan2
- SCN9A | c.3065G>T p.R1022M (on ENST00000303354; = p.R1011M on NM_002977.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV100311842; called by muse, mutect2, varscan2
- SDK1 | c.3083A>T p.H1028L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101268878; called by muse, mutect2
- SELP | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739247; called by muse, mutect2
- SEMA3E | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100317685, COSV57107615; called by muse, mutect2, varscan2
- SEMA6D | c.3222G>T p.*1074Yext*19 (on ENST00000316364 / NM_153618.2; = p.*1012Yext*19 on NM_020858.2) | Nonstop Mutation (SNP) | VAF 51/289 reads (18%) | catalogued as COSV100316594; called by muse, mutect2, varscan2
- SEMA7A | c.1817A>T p.Q606L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99984599; called by muse, mutect2, varscan2
- SERPINE2 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99296437; called by muse, mutect2, varscan2
- SERPINI1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.592); catalogued as COSV99854897; called by muse, mutect2
- SF3B2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.807); catalogued as COSV100488313; called by muse, mutect2, varscan2
- SH2D5 | c.707G>A p.R236H (on ENST00000444387 / NM_001103161.2; = p.R152H on NM_001103160.2) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs752062884, COSV100903869, COSV66707297; called by muse, mutect2, varscan2
- SHANK2 | c.4114G>A p.G1372S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.407); catalogued as rs782434642, COSV99572723; called by muse, mutect2, varscan2
- SIGLECL1 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.753); catalogued as COSV100323843; called by muse, mutect2, varscan2
- SIRT2 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99979253; called by muse, mutect2
- SLC12A1 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100372254; called by muse, mutect2, varscan2
- SLC14A2 | c.843G>T p.L281= | Splice Region (SNP) | VAF 20/81 reads (25%) | catalogued as rs777427004, COSV54911045, COSV99675203; called by muse, mutect2, varscan2
- SLC17A6 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99580976; called by muse, mutect2, varscan2
- SLC18A3 | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339886, COSV100340234; called by muse, mutect2
- SLC20A2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100646011; called by muse, mutect2, varscan2
- SLC22A12 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV100327444; called by muse, mutect2
- SLC26A3 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs765288477, COSV60641616; called by muse, mutect2, varscan2
- SLC2A7 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV101280759, COSV68901283; called by muse, mutect2, varscan2
- SLC30A10 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751451; called by muse, mutect2
- SLC41A3 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100259434; called by muse, mutect2, varscan2
- SLC5A9 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs568504882, COSV52582166, COSV52586744, COSV99361461; called by muse, mutect2, varscan2
- SLX4 | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99567741; called by muse, mutect2
- SMG1 | c.10864G>T p.G3622C | Missense Mutation (SNP) | VAF 102/838 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101245402, COSV67174790; called by muse, mutect2, varscan2
- SNTG1 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99382090; called by muse, mutect2, varscan2
- SORBS2 | c.443C>T p.P148L (on ENST00000284776 / NM_021069.5; = p.P194L on NM_003603.6) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99509891; called by muse, mutect2, varscan2
- SPATA6 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100893772; called by muse, mutect2, varscan2
- SPEG | c.2573G>A p.R858H | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs770384760, COSV100403088, COSV100403596; called by muse, mutect2, varscan2
- SPEG | c.4066A>G p.I1356V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56683920; called by muse, mutect2, varscan2
- SPEM1 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.215); catalogued as COSV100080865; called by muse, mutect2, varscan2
- SPTBN2 | c.4873G>A p.A1625T | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs751736175, COSV100018475; called by muse, mutect2, varscan2
- SRCAP | c.7579C>G p.L2527V | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1264563398, COSV99349551; called by muse, mutect2, varscan2
- SRRM2 | c.6793G>T p.A2265S | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV99241303; called by muse, mutect2, varscan2
- SVEP1 | c.2200G>T p.V734L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV100237506; called by muse, mutect2
- SYCP1 | c.2271A>T p.K757N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV101050803; called by muse, varscan2
- SYK | c.1683G>C p.L561F | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV101002322; called by muse, mutect2, varscan2
- SYNCRIP | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV100784049; called by muse, mutect2, varscan2
- SYNE2 | c.20342A>T p.D6781V | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100647026; called by muse, mutect2, varscan2
- SYT3 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143925; called by muse, mutect2, varscan2
- TAF4B | c.1833A>T p.R611= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99299885; called by mutect2, varscan2
- TAS1R2 | c.2327T>A p.L776H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946156; called by muse, mutect2, varscan2
- TCF12 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99976670; called by muse, mutect2
- TCHH | c.5038G>C p.E1680Q | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV100914929; called by muse, mutect2, varscan2
- TENM1 | c.7731del p.K2577Nfs*32 | Frame Shift Del (DEL) | VAF 46/104 reads (44%) | catalogued as COSV64437227; called by mutect2, pindel, varscan2
- TEX15 | c.4853C>G p.S1618C (on ENST00000256246; = p.S2001C on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV99820912; called by muse, mutect2, varscan2
- TEX19 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100330994; called by muse, mutect2, varscan2
- TG | c.6015C>A p.C2005* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as COSV55066477; called by muse, mutect2, varscan2
- THEG | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100700586; called by muse, mutect2, varscan2
- TIMP3 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1310613651, COSV99830980; called by muse, mutect2, varscan2
- TM6SF2 | c.961C>G p.R321G | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99363677, COSV99363973; called by muse, mutect2, varscan2
- TMEM132B | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as COSV100168851; called by muse, mutect2, varscan2
- TNR | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99688241; called by muse, mutect2, varscan2
- TRAM1L1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751520349, COSV100162052; called by muse, mutect2, varscan2
- TRAM1L1 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100162056, COSV60291919; called by muse, mutect2, varscan2
- TREM2 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as COSV100632536; called by muse, mutect2, varscan2
- TRIM21 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV54345832, COSV99587539; called by muse, mutect2, varscan2
- TRIM50 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV99333794; called by muse, mutect2, varscan2
- TRIM6 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV99546221; called by muse, mutect2, varscan2
- TRPA1 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083487, COSV51558473; called by muse, mutect2
- TRPA1 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100083488; called by muse, mutect2, varscan2
- TSHZ3 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as rs771523387, CM1514913, COSV53683924; called by muse, mutect2, varscan2
- TTLL9 | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100206443, COSV60592768; called by muse, mutect2, varscan2
- TTN | c.74321G>A p.G24774E (on ENST00000591111; = p.G17350E on NM_003319.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV100599765; called by muse, mutect2, varscan2
- TTN | c.66863G>A p.G22288E (on ENST00000591111; = p.G14864E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | PolyPhen probably damaging (0.974); catalogued as COSV60107672; called by muse, mutect2, varscan2
- TTN | c.23006C>T p.S7669F (on ENST00000591111; = p.S6742F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | PolyPhen probably damaging (0.974); catalogued as rs528627735, COSV100599768; called by muse, mutect2, varscan2
- TTN | c.20327C>G p.T6776R (on ENST00000591111; = p.T5849R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/91 reads (47%) | PolyPhen benign (0.203); catalogued as COSV100599769; called by muse, mutect2, varscan2
- TUBGCP5 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1315982494; called by muse, mutect2, varscan2
- U2SURP | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101204369; called by muse, mutect2, varscan2
- U2SURP | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101204370; called by muse, mutect2, varscan2
- UAP1 | c.1234C>G p.Q412E | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV54851887; called by muse, mutect2, varscan2
- UGT1A5 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100529887; called by muse, mutect2, varscan2
- UGT2A2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99683988; called by muse, varscan2
- URGCP | c.948G>T p.W316C (on ENST00000453200 / NM_001077663.3; = p.W307C on NM_017920.4) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs768644545, COSV56245878; called by muse, mutect2, varscan2
- USH2A | c.8964G>T p.K2988N | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100230932; called by muse, mutect2
- USH2A | c.6235A>C p.K2079Q | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as CM115974, COSV100230935, COSV56376400, COSV56425323; called by muse, mutect2, varscan2
- USH2A | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 33/375 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1341016463, COSV100230937; called by muse, mutect2
- USP29 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571855; called by muse, mutect2, varscan2
- VENTX | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.375); catalogued as COSV100384006; called by muse, mutect2, varscan2
- XIRP2 | c.8180A>G p.K2727R (on ENST00000628543; = p.K2902R on NM_152381.6) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV54708266; called by muse, mutect2, varscan2
- XPO4 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.592); catalogued as COSV99688212; called by muse, mutect2, varscan2
- ZAN | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs962853345, COSV100769365; called by muse, mutect2, varscan2
- ZBTB49 | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100552396; called by muse, mutect2, varscan2
- ZCCHC12 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as rs1216776804, COSV59571281; called by muse, mutect2, varscan2
- ZFHX3 | c.5800C>T p.P1934S | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1355044613, COSV51724169; called by muse, mutect2, varscan2
- ZFYVE28 | c.1546A>T p.T516S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99342545; called by muse, mutect2, varscan2
- ZIC3 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54973550; called by muse, mutect2, varscan2
- ZIM2 | c.1175C>A p.P392H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99687804; called by muse, mutect2, varscan2
- ZNF124 | c.437G>C p.G146A (on ENST00000543802 / NM_001297568.1; = p.G84A on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100517675; called by muse, mutect2, varscan2
- ZNF136 | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100677898; called by muse, mutect2, varscan2
- ZNF233 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV100492148; called by muse, mutect2, varscan2
- ZNF276 | c.533G>T p.G178V (on ENST00000443381 / NM_001113525.2; = p.G103V on NM_152287.4) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99234667; called by muse, mutect2
- ZNF462 | c.5365C>T p.R1789C | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1351192935, COSV99471068; called by muse, mutect2, varscan2
- ZNF468 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 44/180 reads (24%) | catalogued as COSV99700397; called by muse, mutect2, varscan2
- ZNF479 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100482576; called by muse, mutect2, varscan2
- ZNF521 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762549593, COSV100831595; called by muse, mutect2, varscan2
- ZNF534 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV99989525; called by muse, mutect2, varscan2
- ZNF572 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100073866; called by muse, mutect2
- ZNF615 | c.1685A>T p.H562L | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100943732; called by muse, mutect2, varscan2
- ZNF616 | c.1086C>G p.F362L | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100348171; called by muse, mutect2
- ZNF675 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV100704954; called by muse, mutect2, varscan2
- ZNF701 | c.1481A>T p.H494L (on ENST00000301093; = p.H428L on NM_018260.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99990715; called by muse, mutect2, varscan2
- ZNF99 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs774007981, COSV101233743; called by muse, mutect2, varscan2
- ZNFX1 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs143179718; called by muse, mutect2
- ZP3 | c.988C>G p.P330A (on ENST00000394857 / NM_001110354.2; = p.P279A on NM_007155.6) | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100334475; called by muse, mutect2, varscan2
- ZSCAN10 | c.1870C>A p.R624S (on ENST00000252463; = p.R679S on NM_032805.3) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99373879; called by muse, mutect2, varscan2
- ABCC3 | c.1519del p.E507Sfs*5 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.15300del p.K5101Nfs*13 | Frame Shift Del (DEL) | VAF 22/204 reads (11%) | called by mutect2, pindel, varscan2
- AP3D1 | c.1818del p.V607Wfs*107 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel*, varscan2
- ATP11A | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCBE1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPP10 | c.1501del p.V501Sfs*21 | Frame Shift Del (DEL) | VAF 19/161 reads (12%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.1446_1456dup p.K486Mfs*6 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- FABP4 | c.203del p.G68Afs*18 | Frame Shift Del (DEL) | VAF 70/196 reads (36%) | called by mutect2, pindel, varscan2
- FCGBP | c.7880C>A p.S2627Y | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); called by muse, mutect2
- MAP3K19 | c.139-9_144del p.X47_splice | Splice Site (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel*
- MUC2 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NAV2 | c.211_213delinsTT p.G71Lfs*29 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by pindel, varscan2*
- PCDH7 | c.3168del p.S1056Rfs*71 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- PPP4R1 | c.2744T>A p.M915K (on ENST00000400556 / NM_001042388.3; = p.M898K on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- PRAMEF18 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 28/430 reads (7%) | called by muse, mutect2
- SMARCC2 | c.3588_3600del p.D1198Rfs*81 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- TG | c.7813del p.R2605Efs*49 | Frame Shift Del (DEL) | VAF 17/158 reads (11%) | called by mutect2, pindel, varscan2
- TRDJ2 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 39/191 reads (20%) | called by muse, mutect2, varscan2
- XPOT | c.413del p.G138Efs*2 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.2267G>T p.R756I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF423 | c.2746dup p.D916Gfs*10 (on ENST00000563137 / NM_001379286.1; = p.D908Gfs*10 on NM_015069.4) | Frame Shift Ins (INS) | VAF 58/231 reads (25%) | called by mutect2, pindel, varscan2
- ACAD10 | c.609G>T p.L203= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100563907; called by muse, mutect2, varscan2
- ADAM19 | c.1818G>T p.R606= | Silent (SNP) | VAF 32/194 reads (16%) | catalogued as COSV99976434; called by muse, mutect2, varscan2
- ADAMTS12 | c.2004T>C p.C668= | Silent (SNP) | VAF 42/128 reads (33%) | catalogued as COSV100710433; called by muse, mutect2, varscan2
- ADAMTS18 | c.3390G>A p.L1130= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs1328382450, COSV99271597; called by muse, mutect2, varscan2
- ADAMTS18 | c.1686A>G p.E562= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99271599; called by muse, varscan2
- ADAMTS9 | c.4983C>A p.G1661= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99898932; called by muse, mutect2, varscan2
- ANKRD30A | c.1866C>A p.A622= (on ENST00000611781; = p.A566= on NM_052997.2) | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as COSV100653078; called by muse, mutect2, varscan2
- ASPRV1 | c.594C>G p.L198= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs754850728, COSV100208421; called by muse, mutect2, varscan2
- ATP7A | c.288G>A p.L96= | Silent (SNP) | VAF 124/412 reads (30%) | catalogued as COSV100430443; called by muse, mutect2, varscan2
- BCL2L2 | c.468G>T p.L156= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as COSV99161478; called by muse, mutect2, varscan2
- BGN | c.972C>G p.G324= | Silent (SNP) | VAF 65/230 reads (28%) | catalogued as COSV100525117; called by muse, mutect2, varscan2
- CACNB4 | c.135C>T p.F45= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as COSV99137876; called by muse, mutect2, varscan2
- CAPN2 | c.1113G>T p.A371= | Silent (SNP) | VAF 25/248 reads (10%) | catalogued as rs145344369, COSV99688660; called by muse, mutect2, varscan2
- CCBE1 | c.501G>T p.R167= | Silent (SNP) | VAF 33/328 reads (10%) | catalogued as COSV101232789; called by muse, mutect2, varscan2
- CCDC170 | c.1626G>T p.V542= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV99498229; called by muse, mutect2, varscan2
- CCDC178 | c.2445G>T p.V815= (on ENST00000383096 / NM_001105528.3; = p.V777= on NM_198995.3) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV55777387; called by muse, mutect2, varscan2
- CCDC80 | c.714G>A p.L238= | Silent (SNP) | VAF 39/244 reads (16%) | catalogued as rs1363922966, COSV52816274, COSV52820477; called by muse, mutect2, varscan2
- CDC27 | c.1884C>T p.I628= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV50382612, COSV50657329; called by mutect2, varscan2
- CDH22 | c.1338G>T p.A446= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100952777; called by muse, mutect2
- CDHR2 | c.666C>A p.S222= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV99991184; called by muse, mutect2, varscan2
- CHD4 | c.5610A>C p.P1870= (on ENST00000357008 / NM_001363606.2; = p.P1880= on NM_001273.5) | Silent (SNP) | VAF 100/633 reads (16%) | catalogued as COSV100444743; called by muse, mutect2, varscan2
- CLIC6 | c.1518G>T p.V506= (on ENST00000360731 / NM_001317009.2; = p.V488= on NM_053277.3) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100659154; called by muse, mutect2, varscan2
- CNTNAP5 | c.780G>T p.L260= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV70485399; called by muse, mutect2, varscan2
- COL6A3 | c.9081C>T p.A3027= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV55098124; called by muse, mutect2, varscan2
- CR1 | c.5367C>A p.P1789= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as COSV100887432; called by muse, mutect2, varscan2
- CRYBA2 | c.390G>T p.L130= | Silent (SNP) | VAF 24/201 reads (12%) | catalogued as COSV99838058; called by muse, mutect2, varscan2
- CRYGB | c.438G>T p.L146= | Silent (SNP) | VAF 46/239 reads (19%) | catalogued as COSV99649913; called by muse, mutect2, varscan2
- CTSF | c.891C>G p.A297= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100074158; called by muse, mutect2, varscan2
- DIP2C | c.2869C>T p.L957= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV99790536; called by muse, mutect2, varscan2
- DMBT1 | c.1452G>A p.S484= | Silent (SNP) | VAF 58/376 reads (15%) | catalogued as rs780136326, COSV57562287; called by muse, mutect2, varscan2
- DNAH5 | c.10668A>G p.P3556= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV99446279; called by muse, mutect2, varscan2
- DNAJC6 | c.1518A>C p.A506= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99674265; called by muse, mutect2, varscan2
- DOCK6 | c.4146G>C p.G1382= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99625009; called by muse, mutect2, varscan2
- DOK2 | c.624C>A p.T208= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99374599; called by muse, mutect2, varscan2
- DPAGT1 | c.456C>T p.P152= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100830685; called by muse, mutect2, varscan2
- DRC1 | c.81C>T p.V27= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99985122; called by muse, mutect2, varscan2
- EDA | c.186A>T p.L62= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as COSV100140771; called by muse, mutect2, varscan2
- EPB41L1 | c.2508C>T p.V836= | Silent (SNP) | VAF 27/201 reads (13%) | catalogued as rs762248297, COSV52433739; called by muse, mutect2, varscan2
- ERCC8 | c.1134G>T p.L378= (on ENST00000265038; = p.L359= on NM_000082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV99410242; called by muse, mutect2, varscan2
- ESPNL | c.921G>C p.A307= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100547659; called by muse, mutect2, varscan2
- ETV3L | c.1041C>A p.P347= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV101485565; called by muse, mutect2, varscan2
- FAM135B | c.2544C>A p.P848= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99420576; called by muse, mutect2
- FAM209B | c.405T>A p.G135= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100990934; called by muse, mutect2
- FAM217A | c.42G>T p.V14= | Silent (SNP) | VAF 54/257 reads (21%) | catalogued as COSV99212691; called by muse, mutect2, varscan2
- FAM237A | c.27G>T p.G9= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV101405572; called by muse, mutect2, varscan2
- FLNA | c.3175C>T p.L1059= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100774390; called by muse, mutect2, varscan2
- FLNC | c.4437G>T p.V1479= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV57955909, COSV57955994; called by muse, mutect2
- FRAS1 | c.7185C>G p.L2395= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1474911370, COSV99349343; called by muse, mutect2, varscan2
- GCSAML | c.285C>T p.L95= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100825900, COSV63577280; called by muse, mutect2, varscan2
- GFOD2 | c.390C>T p.F130= | Silent (SNP) | VAF 21/191 reads (11%) | catalogued as rs142530623, COSV99263443; called by muse, mutect2, varscan2
- HIRA | c.684C>T p.L228= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV99600037; called by muse, mutect2
- HOXC11 | c.828G>A p.V276= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as COSV99678345; called by muse, mutect2, varscan2
- HRNR | c.2301A>T p.R767= | Silent (SNP) | VAF 27/258 reads (10%) | catalogued as COSV100913094; called by muse, mutect2, varscan2
- HTT | c.543G>T p.R181= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV100750542; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.282C>T p.S94= | Silent (SNP) | VAF 67/1008 reads (7%) | catalogued as rs769043817; called by muse, mutect2
- IL20 | c.30T>C p.L10= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV100894126; called by muse, mutect2, varscan2
- IL3RA | c.468G>A p.T156= | Silent (SNP) | VAF 80/465 reads (17%) | catalogued as rs1445376991, COSV58430704; called by muse, mutect2, varscan2
- INA | c.132C>A p.S44= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100878590; called by muse, mutect2
- IQGAP3 | c.465C>T p.A155= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1389180681, COSV100752093; called by muse, mutect2, varscan2
- ITIH5 | c.306T>A p.I102= | Silent (SNP) | VAF 20/233 reads (9%) | catalogued as COSV56898631, COSV99904005; called by muse, mutect2
- KCNG1 | c.114G>A p.A38= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100856998, COSV65370532; called by muse, varscan2
- KLK11 | c.360A>T p.T120= (on ENST00000594768 / NM_144947.3; = p.T88= on NM_006853.3) | Silent (SNP) | VAF 65/238 reads (27%) | catalogued as COSV99141826; called by muse, mutect2, varscan2
- KRT6A | c.675G>T p.L225= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as COSV100416796; called by muse, mutect2, varscan2
- LRRTM1 | c.1140C>T p.N380= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs751171315, COSV99702031; called by mutect2, varscan2
- MATN1 | c.1038C>G p.S346= | Silent (SNP) | VAF 43/233 reads (18%) | catalogued as COSV101056210; called by muse, mutect2, varscan2
- MC4R | c.447T>C p.F149= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs896726218, COSV100235896; called by muse, mutect2, varscan2
- MED16 | c.2004G>A p.L668= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99515236; called by muse, mutect2, varscan2
- MEF2D | c.711G>T p.V237= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV61730402; called by muse, mutect2
- MGAM | c.4302A>T p.P1434= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV101527412; called by muse, mutect2, varscan2
- NCKAP5L | c.2925G>T p.A975= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100258472; called by muse, mutect2, varscan2
- NHS | c.1593G>T p.P531= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV101196450; called by muse, mutect2, varscan2
- NHSL2 | c.198T>A p.P66= (on ENST00000510661; = p.P432= on NM_001013627.2) | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV101029932; called by muse, mutect2, varscan2
- NLRC5 | c.1956C>T p.A652= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as COSV99346685; called by muse, mutect2, varscan2
- NMUR2 | c.489C>A p.A163= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99676701; called by muse, mutect2, varscan2
- NOX5 | c.231C>T p.I77= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as COSV99533456; called by muse, mutect2, varscan2
- NTM | c.516C>A p.I172= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV100867723, COSV66175835; called by muse, mutect2, varscan2
- OLFML2A | c.1854C>T p.N618= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs757514051, COSV56585468; called by muse, mutect2, varscan2
- OR2C3 | c.204C>T p.P68= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100825634; called by muse, mutect2, varscan2
- OR51T1 | c.798C>A p.L266= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV100434328; called by muse, mutect2, varscan2
- OR6C74 | c.555C>T p.L185= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs764705397, COSV100667706; called by muse, mutect2, varscan2
- OR6K6 | c.144G>A p.A48= (on ENST00000368144; = p.A24= on NM_001005184.1) | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as rs147601748, COSV63744717, COSV63744838; called by muse, mutect2
- OR8B12 | c.639C>A p.V213= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100172684, COSV60912423; called by muse, mutect2
- PCDHGA10 | c.1785G>T p.V595= | Silent (SNP) | VAF 28/227 reads (12%) | catalogued as COSV99533256; called by muse, mutect2, varscan2
- PCDHGA4 | c.1836C>A p.S612= | Silent (SNP) | VAF 71/441 reads (16%) | catalogued as COSV99533247; called by muse, mutect2, varscan2
- PI4KA | c.5713C>A p.R1905= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99744907; called by muse, mutect2
- PIGT | c.1002C>T p.I334= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as rs748215362, COSV99648752; called by muse, mutect2, varscan2
- PSG3 | c.675C>A p.A225= | Silent (SNP) | VAF 97/846 reads (11%) | catalogued as rs376185249, COSV100548744; called by muse, mutect2, varscan2
- PXK | c.742C>T p.L248= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100243943, COSV57091107; called by muse, mutect2, varscan2
- RFX5 | c.705C>T p.L235= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV51837972; called by muse, mutect2, varscan2
- RHBG | c.861G>A p.A287= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as rs376540119; called by muse, mutect2, varscan2
- ROBO1 | c.3969T>C p.D1323= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV101458365; called by muse, mutect2
- RPS5 | c.402G>A p.V134= | Silent (SNP) | VAF 53/190 reads (28%) | catalogued as COSV52192031; called by muse, mutect2, varscan2
- RSU1 | c.42G>A p.E14= | Silent (SNP) | VAF 31/256 reads (12%) | catalogued as COSV100590283; called by muse, mutect2, varscan2
- RYR1 | c.10038G>A p.V3346= | Silent (SNP) | VAF 34/320 reads (11%) | catalogued as COSV100614937; called by muse, mutect2
- RYR2 | c.5316T>C p.S1772= | Silent (SNP) | VAF 25/206 reads (12%) | catalogued as COSV100768761; called by muse, mutect2, varscan2
- RYR2 | c.13710C>A p.P4570= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs1368100707, COSV100768764; called by muse, mutect2, varscan2
- SAMD9L | c.4227A>G p.Q1409= | Silent (SNP) | VAF 98/230 reads (43%) | catalogued as COSV59081944; called by muse, mutect2, varscan2
- SAMD9L | c.225G>A p.L75= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as COSV100560444; called by muse, mutect2, varscan2
- SCAMP5 | c.429G>A p.T143= | Silent (SNP) | VAF 53/373 reads (14%) | catalogued as rs778160445, COSV62642807; called by muse, mutect2, varscan2
- SEMA4A | c.735C>T p.F245= | Silent (SNP) | VAF 31/297 reads (10%) | catalogued as COSV100740485; called by muse, mutect2, varscan2
- SERPINB11 | c.711C>A p.P237= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV101236170; called by muse, mutect2
- SERPINI2 | c.90A>C p.A30= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV52989302, COSV99247673; called by muse, mutect2
- SGIP1 | c.1497C>A p.P499= | Silent (SNP) | VAF 40/292 reads (14%) | catalogued as COSV52773607; called by muse, varscan2
- SGIP1 | c.1536C>A p.T512= | Silent (SNP) | VAF 32/268 reads (12%) | catalogued as COSV99390825; called by muse, varscan2
- SLC12A3 | c.489G>A p.T163= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs766590120, COSV99343909; called by muse, mutect2, varscan2
- SLC27A1 | c.1677C>T p.P559= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99393081; called by muse, mutect2, varscan2
- SLC2A3 | c.939G>T p.V313= | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as COSV99306336; called by muse, mutect2, varscan2
- SLC35C2 | c.759C>T p.A253= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as COSV99709143; called by muse, mutect2, varscan2
- SLC35E3 | c.894G>A p.K298= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100097974; called by muse, mutect2, varscan2
- SLC35G3 | c.441C>T p.L147= | Silent (SNP) | VAF 129/428 reads (30%) | catalogued as COSV99268342; called by muse, mutect2, varscan2
- SLC38A10 | c.1053G>T p.A351= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs758222332, COSV99917274; called by muse, mutect2, varscan2
- SLC8A2 | c.336C>T p.A112= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs1170034305, COSV99369742; called by muse, mutect2, varscan2
- SLIT3 | c.444C>A p.I148= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100265899, COSV60628768; called by muse, mutect2, varscan2
- SMPD4 | c.2232C>T p.V744= (on ENST00000409031 / NM_017951.4; = p.V715= on NM_017751.4) | Silent (SNP) | VAF 35/251 reads (14%) | catalogued as rs752802268, COSV100302256; called by muse, mutect2, varscan2
- SP1 | c.1851G>A p.S617= (on ENST00000327443 / NM_138473.3; = p.S610= on NM_003109.1) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs374193831, COSV100540463; ClinVar: likely benign; called by muse, mutect2
- SPAG6 | c.894G>T p.V298= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV100510054; called by muse, mutect2, varscan2
- SRRM1 | c.2307C>T p.S769= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as COSV100104219; called by muse, mutect2, varscan2
- STYXL2 | c.3016C>A p.R1006= | Silent (SNP) | VAF 80/179 reads (45%) | catalogued as COSV54811450; called by muse, mutect2, varscan2
- SULF2 | c.741G>T p.T247= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV100737055; called by muse, mutect2, varscan2
- SYNE4 | c.843C>G p.P281= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99430855, COSV99430893; called by muse, mutect2, varscan2
- TBX3 | c.222C>G p.T74= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99983320; called by muse, mutect2, varscan2
- TCERG1L | c.390C>A p.S130= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV100893993; called by muse, mutect2, varscan2
- TCF4 | c.1596G>A p.K532= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1457678224, COSV100610831, COSV61907041; called by muse, mutect2, varscan2
- TCFL5 | c.1341G>A p.L447= | Silent (SNP) | VAF 17/169 reads (10%) | catalogued as rs1270233143, COSV99415622; called by muse, mutect2
- THSD1 | c.1758G>A p.R586= | Silent (SNP) | VAF 17/128 reads (13%) | catalogued as COSV99318772; called by muse, mutect2, varscan2
- TLR1 | c.159G>T p.S53= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs55851227, COSV100458349; called by muse, mutect2, varscan2
- TMCC3 | c.702G>A p.A234= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs201555160; called by muse, mutect2, varscan2
- TMPO | c.1584A>T p.T528= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV99701920; called by muse, mutect2, varscan2
- TNS3 | c.2967G>T p.P989= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100235066; called by muse, mutect2, varscan2
- TP53INP2 | c.654C>T p.F218= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100749932; called by muse, mutect2, varscan2
- TRAPPC9 | c.2097C>T p.I699= | Silent (SNP) | VAF 23/195 reads (12%) | catalogued as COSV101226922; called by muse, mutect2, varscan2
- TSC1 | c.1173A>T p.P391= | Silent (SNP) | VAF 120/431 reads (28%) | catalogued as COSV100051348; called by muse, mutect2, varscan2
- TTC30B | c.732C>T p.V244= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as rs746611340, COSV101282773; called by muse, mutect2, varscan2
- TUBGCP6 | c.3507C>T p.I1169= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs765438622, COSV99955051; called by muse, mutect2, varscan2
- UCK2 | c.447C>T p.F149= | Silent (SNP) | VAF 54/521 reads (10%) | catalogued as COSV100902874; called by muse, mutect2, varscan2
- UXS1 | c.363C>T p.F121= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV99307989; called by muse, mutect2, varscan2
- VPS35L | c.2083A>C p.R695= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as COSV99219987; called by muse, mutect2, varscan2
- WDR38 | c.294G>A p.L98= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as COSV100793803; called by muse, mutect2, varscan2
- WNT4 | c.177G>A p.R59= | Silent (SNP) | VAF 40/225 reads (18%) | catalogued as rs751464895, COSV99268625; called by muse, mutect2, varscan2
- XPC | c.2073G>T p.L691= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV99542130; called by muse, mutect2
- ZBTB21 | c.2670A>T p.A890= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100176969; called by muse, mutect2, varscan2
- ZFP69 | c.1539T>C p.H513= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV101018135; called by muse, mutect2, varscan2
- ZFX | c.1437G>A p.K479= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100457387; called by muse, mutect2, varscan2
- ZIC1 | c.630C>T p.A210= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV51553212; called by muse, mutect2, varscan2
- ZMIZ2 | c.258A>G p.P86= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV99536657; called by muse, mutect2
- ZMYM6 | c.216A>G p.A72= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs765146633, COSV100451563; called by muse, mutect2, varscan2
- ZNF318 | c.5754G>A p.E1918= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV100546020; called by muse, mutect2, varscan2
- ZNF398 | c.1920A>G p.G640= (on ENST00000475153 / NM_170686.3; = p.G469= on NM_020781.4) | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV60065167; called by muse, mutect2, varscan2
- ZNF408 | c.1533G>T p.L511= | Silent (SNP) | VAF 21/212 reads (10%) | catalogued as COSV100305386; called by muse, mutect2, varscan2
- ZNF423 | c.1038C>A p.V346= (on ENST00000563137 / NM_001379286.1; = p.V338= on NM_015069.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99280463; called by muse, mutect2, varscan2
- ZNF438 | c.1332A>T p.I444= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as COSV100061451; called by muse, mutect2, varscan2
- ZNF468 | c.888G>A p.E296= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as COSV99700398; called by muse, mutect2, varscan2
- ZNF536 | c.3759G>T p.R1253= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs141558241; called by muse, mutect2, varscan2
- ZNF665 | c.1791C>G p.V597= (on ENST00000600412; = p.V662= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101128502, COSV67214826; called by muse, mutect2, varscan2
- ZNF7 | c.298C>T p.L100= | Silent (SNP) | VAF 37/280 reads (13%) | catalogued as rs1419931851, COSV100295707; called by muse, mutect2, varscan2
- ZNF80 | c.648C>T p.P216= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV100351953; called by muse, mutect2
- ZNF835 | c.402G>T p.G134= | Silent (SNP) | VAF 29/222 reads (13%) | catalogued as COSV101606295; called by muse, mutect2, varscan2
- CCNQP1 | n.20T>A | RNA (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- DAZAP1 | c.1049-979A>G | Intron (SNP) | VAF 20/152 reads (13%) | catalogued as COSV99245069; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415260 C>T | 5'Flank (SNP) | VAF 24/328 reads (7%) | catalogued as COSV52569848; called by muse, mutect2
- DPP6 | c.*299T>C | 3'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as rs775048399, COSV100123723; called by muse, mutect2, varscan2
- MCM7 | c.1849-369C>T | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as rs372015556; called by muse, mutect2, varscan2
- MIR513A2 | n.77T>A | RNA (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- NRM | c.*2G>A | 3'UTR (SNP) | VAF 17/117 reads (15%) | catalogued as COSV99223549; called by muse, mutect2, varscan2
- OBSCN | c.11660-1858G>A | Intron (SNP) | VAF 30/291 reads (10%) | catalogued as COSV52799529, COSV99474785; called by muse, mutect2, varscan2
- PDXK | c.88-1556G>A | Intron (SNP) | VAF 20/137 reads (15%) | catalogued as rs748702111, COSV99376176; called by muse, mutect2, varscan2
- SLC22A20P | n.1018C>G | RNA (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- TRPM3 | c.979+17813G>T | Intron (SNP) | VAF 66/150 reads (44%) | catalogued as COSV100676890; called by muse, mutect2, varscan2
